TCGA case TCGA-DD-A4NQ — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c05720fe-19c1-4cff-819b-6806b26fc312

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Dead; Days to death: 373 days (1.0 years).

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 60.5 years (22,111 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Macro.
   Treatment given: Treatment type: Radioembolization; Days to treatment start: 148 days; Embolic agent: Y-90 Therasphere.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sorafenib; Days to treatment start: 151 days; Days to treatment end: 290 days.
   Treatment given: Treatment type: Radioembolization; Days to treatment start: 211 days; Embolic agent: Y-90 Therasphere.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 60.9 years (22,237 days); Days to diagnosis: 126 days; Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 126 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 126 days.
- Days to follow up: 373 days (1.0 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Alpha Fetoprotein 141 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Total Bilirubin 0.7 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Prothrombin Time 10.1 Seconds [Blood test normal range lower: 8.4; Blood test normal range upper: 12].
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.3].
- Platelets 283 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Albumin 4.4 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis B Infection / Tobacco, NOS; Viral hepatitis serology tests: Hepatitis C Virus RNA / Hepatitis B Surface Antigen / HBV Surface Antibody / HBV Core Antibody.
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 159 cm; BMI: 29.7.

Family history
- Relatives with cancer history count: 1.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-A4NQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-DD-A4NQ-01A-02-TSB: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-A4NQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-A4NQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-DD-A4NQ-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-DD-A4NQ-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple; Hepatic inflammation adj tissue: Mild.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis C Virus RNA; Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: HBV Surface Antibody; Viral hepatitis serology: HBV Core Antibody.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: No.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 373 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 373 days; disease-free interval: event (new tumor event after initially disease-free), 126 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 126 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-A4NQ-01A-21D-A28W-01): tumor purity 0.41, ploidy 2.02, whole-genome doublings 0.
